Gene-level copy-number profile of tumor specimen TCGA-06-5408-01A from TCGA case TCGA-06-5408, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.9 years (20,063 days).
Specimen TCGA-06-5408-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.8a43212c-31a9-4a22-b81e-2e75e7f60f37.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-5408-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d19d1797-d43d-4342-b8c7-0eaa69893c9d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 7,583; copy number 2: 49,390; copy number 3: 2,633; copy number 4: 80; copy number 5: 55; copy number 22: 24; copy number 24: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-5408-01A-01D-1694-01): tumor purity 0.9, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:161,347,417–162,727,775, 1 gene (within-gene range 0–1): PRKN.
- chr6:162,568,379–165,309,605, 28 genes: KRT8P44, PACRG, AL590286.1, AL590286.2, PACRG-AS2, AL137182.1, PACRG-AS3, PACRG-AS1, AL031121.2, AL031121.3, AL031121.1, CAHM, QKI, AL445307.1, AL078602.1, AL137005.1, RN7SL366P, AL136225.1, Z97205.2, Z97205.1, Z97205.3, AL139190.1, AL358972.1, AL450345.2, AL450345.1, AL133538.1, AL136100.1, C6orf118.
- chr9:21,802,636–22,029,594, 8 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes: AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 93 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,185,071–54,938,184, 14 genes, copy number 24: AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1.
- chr7:55,179,750–55,789,474, 22 genes, copy number 22: EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P.
- chr7:55,797,946–55,798,876, 2 genes, copy number 22: AC092647.4, CICP12.
- chr7:91,264,433–94,077,157, 54 genes, copy number 5: FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2.
- chr7:94,311,138–94,347,063, 1 gene, copy number 5 (within-gene range 3–5): AC002074.2.

Autosomal genes at a single copy (total copy number 1): 7,583. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
